Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A4KI, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A4KI-01A (Primary Tumor).

[page 1 of 3]
Collected: _____ DOB _____ Sex: M
Received: _____ Physician: _____
Case type: Surgical Case Accession: _____

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) BIOPSY IDENTIFY PARATHYROID (LEFT INFERIOR):

Adipose tissue, negative for tumor, no parathyroid parenchyma identified

(B) TOTAL THYROID:

PAPILLARY THYROID CARCINOMA, WITH HIGHER-GRADE INSULAR AREAS AND NECROSIS

Location: Bilateral

Multi-focal: Yes

Size = 3.4 cm, Largest focus, Left

Extrathyroidal extension: favor into fibrous tissue

Lymphovascular invasion: PRESENT

Resection Margins: Negative

Background Thyroid: Multinodular adenomatous goiter

Lymph nodes: No lymph nodes present

Intrathyroidal nodule, 1.3 cm left lobe pending immunos, see addendum.

(C) LEFT LEVEL 3 LYMPH NODE:

One lymph node, negative for tumor (0/1)

ICD-0-3

(D) LEFT PARATRACHEAL SOFT TISSUE:

Normal cellular parathyroid gland

Lymph nodes are not identified.

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

fw
10/4/12

GROSS DESCRIPTION

(A) BIOPSY IDENTIFY PARATHYROID (LEFT INFERIOR) FROZEN - A tan-red soft tissue (0.2 x 0.2 x 0.1 cm). A touch prep is performed. The specimen weighs 0.317 grams.

SECTION CODE: A1, submitted in toto for frozen section.

*FS/DX: FIBROADIPOSE TISSUE; NO PARATHYROID PRESENT.

(B) TOTAL THYROID STITCH LEFT LOBE - Received is a total thyroidectomy specimen oriented by the surgeon with stitch designating left lobe (8.0 x 6.0 x 5.0 cm) with isthmus (4.0 x 2.5 x 2.3 cm) and right lobe (8.0 x 4.0 x 3.0 cm) all surfaced by smooth glistening intact capsule. The specimen is serially sectioned from superior to inferior to reveal a tan-pink to gray-white partly hemorrhagic, partly cystic cut surface of the left lobe. Left lobe is remarkable for areas of necrosis. Isthmus is serially sectioned from lateral to medial to reveal two well circumscribed gray-white, firm nodules measuring 1.1 x 0.8 x 0.8 cm and 1.5 x 1.4 x 1.4 cm with a moderate amount of normal appearing thyroid parenchyma. The right lobe is serially sectioned from superior to inferior to reveal a partly circumscribed tan, partly lobulated mass (3.4 x 2.7 x 2.4 cm) that is predominantly located in the mid to lower pole. The remaining thyroid parenchyma ranges from tan-gray, partly necrotic to red-brown and normal

[page 2 of 3]
DB:
Physician:

Sex: M

Collected:
Received

Pathologist:
Case type: Surgical Case

Accession:

appearing. Twenty percent of the right lobe is normal appearing. Tumor and normal tissue submitted to the head and neck bank. Representative sections submitted.

SECTION CODE: B1-B10, representative sections of the left lobe from superior to inferior; B11, one nodule from isthmus; B12, B13, representative section of second nodule to normal parenchyma; B14-B20, representative section of right lobe from superior to inferior.

(C) LEFT LEVEL 3 LYMPH NODE – A single dark red lymph node (1.5 x 1.0 x 0.6 cm).

SECTION CODE: C1, serially sectioned and entirely submitted for frozen section.

*FS/DX: BENIGN LYMPH NODE.

(D) LEFT PARATRACHEAL SOFT TISSUE – Unoriented portion of tan-pink congested appearing soft tissue (2.5 x 2.0 x 1.4 cm) that is serially sectioned to reveal unremarkable cut surfaces. Specimen is submitted entirely in D1-D4.

CLINICAL HISTORY

Multiple thyroid nodules

SNOMED CODES

T-B6000, M-83403, M-Y3420

"Some tests reported here may have been developed and performance characteristics determined by
These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Page 2 of 3	
Surgical Pathology Report	
File under: Pathology	

[page 3 of 3]
DOB:
Physician:

Sex: M

Collected: Pathologist: Accession:
Received: Case type: Surgical Case

ADDENDUM

This modified report is being issued to report special studies/IHC/Molecular studies.

Addendum completed by

COMMENT

The distinct intrathyroidal nodule was evaluated by TTF-1 which is positive and PTH is negative. The above interpretation remains unchanged.

Entire report and diagnosis completed by:

Surgical Pathology Report		Page 3 of 3	
File under: Pathology			
Dual/Synchronous; Primary noted			

Source: NCI Genomic Data Commons file c074479d-931a-485b-af8c-e763134422f3 (TCGA-EL-A4KI.D24515CA-CEF9-4311-B03D-3739277C8DE7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).